Somatic mutation profile of cancer-model specimen HCM-BROD-0453-C16-85A (3D Organoid, passage 6; aliquot HCM-BROD-0453-C16-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-BROD-0453-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 40.2 years (14,671 days).
Specimen HCM-BROD-0453-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 070a5310-117a-4bf9-9141-5ceaaba196d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0453-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0453-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1d95597-a8c3-4a32-a54f-d918ec317b19

The open-access MAF lists 93 somatic variants for this specimen: 62 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 28, Frame Shift Del 3, 3'UTR 2, Nonsense Mutation 2, In Frame Del 2, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 609/609 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 359/359 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1457870168, COSV61261330; called by muse, mutect2
- ALDH3B2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 338/876 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs1377353543; called by muse, mutect2
- CTNNA2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 201/506 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1468771318, COSV63570647, COSV63578276; called by muse, mutect2, varscan2
- CYFIP2 | c.3352G>A p.E1118K (on ENST00000616178 / NM_001291722.2; = p.E1093K on NM_014376.4) | Missense Mutation (SNP) | VAF 296/519 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV59034733; called by muse, mutect2, varscan2
- DPY19L2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 80/678 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1218448749; called by muse, varscan2
- DUOX1 | c.3992C>T p.T1331M | Missense Mutation (SNP) | VAF 288/518 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs374344810; called by muse, mutect2, varscan2
- EBF2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1278825155, COSV68779642; called by muse, mutect2, varscan2
- FAM104A | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 289/1082 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs199818438; called by muse, mutect2, varscan2
- GRIN3A | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV62450142; called by muse, mutect2
- GRM6 | c.2020C>A p.R674S | Missense Mutation (SNP) | VAF 286/592 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51439074; called by muse, mutect2, varscan2
- IGHM | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 592/592 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs530414987; called by muse, mutect2, varscan2
- KCNA5 | c.1734G>T p.R578S | Missense Mutation (SNP) | VAF 180/639 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV52909401; called by muse, mutect2, varscan2
- KCNN4 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 167/552 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs777143204; called by muse, mutect2, varscan2
- LRRC15 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 29/767 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1560045282; called by muse, mutect2
- LRRC8E | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 176/681 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs746469664; called by muse, mutect2, varscan2
- MAGEC3 | c.1706G>T p.W569L | Missense Mutation (SNP) | VAF 208/542 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100025959; called by muse, mutect2, varscan2
- MAGEE1 | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 256/383 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63908813, COSV63909025; called by muse, mutect2, varscan2
- MYO15A | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 322/686 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.014); catalogued as rs749218522, COSV52759608; called by muse, mutect2, varscan2
- NGFR | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 303/637 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs748153154, COSV99412584; called by muse, mutect2, varscan2
- NSD3 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.401); catalogued as COSV57618283; called by muse, mutect2
- OR5B21 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 13/414 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1047628057; called by muse, mutect2
- PIK3C2G | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56798568; called by muse, mutect2, varscan2
- PLCG1 | c.3685C>T p.R1229W (on ENST00000373271 / NM_182811.2; = p.R1230W on NM_002660.3) | Missense Mutation (SNP) | VAF 157/704 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769763292; called by muse, mutect2, varscan2
- PLS3 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99171800; called by muse, mutect2, varscan2
- POLR3B | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 171/371 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs750899096; called by muse, mutect2, varscan2
- PXDN | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs765019551, COSV53236859, COSV99414195; called by muse, mutect2, varscan2
- SEC24C | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 196/758 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as rs771438137; called by muse, mutect2, varscan2
- SEMA3D | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1265790609, COSV52387550; called by muse, mutect2, varscan2
- TGFBR2 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 350/350 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99848573; called by muse, mutect2, varscan2
- XRN2 | c.2653G>A p.V885I | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs574867275; called by muse, mutect2, varscan2
- ZNF613 | c.1816A>G p.S606G (on ENST00000293471 / NM_001031721.4; = p.S570G on NM_024840.4) | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV53272786; called by muse, mutect2, varscan2
- BCHE | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 67/299 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CCM2 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- DDX39B | c.95del p.K32Rfs*87 | Frame Shift Del (DEL) | VAF 186/1104 reads (17%) | called by mutect2, pindel, varscan2
- EPHA7 | c.1534G>T p.V512F | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2
- EPHA7 | c.1532A>T p.Y511F | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GOLGA8S | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.046); called by muse, varscan2
- HSP90B1 | c.1660T>G p.F554V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KIF7 | c.2177A>G p.E726G | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP1B | c.12677G>T p.R4226I | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MAML2 | c.3163A>G p.S1055G | Missense Mutation (SNP) | VAF 221/546 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEF2C | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MRGPRG | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 38/1394 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MTF2 | c.1008A>T p.E336D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO1D | c.1143_1150delinsTT p.L382_I384delinsF | In Frame Del (DEL) | VAF 41/151 reads (27%) | called by pindel, varscan2*
- NAA30 | c.428_444del p.S143Cfs*58 | Frame Shift Del (DEL) | VAF 157/428 reads (37%) | called by pindel, varscan2
- NCLN | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 117/440 reads (27%) | called by muse, mutect2, varscan2
- NUP188 | c.2340_2342del p.I780del | In Frame Del (DEL) | VAF 260/265 reads (98%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.2236G>A p.G746R | Missense Mutation (SNP) | VAF 32/539 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- PGA5 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 109/795 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PJA2 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PPM1F | c.528_531del p.F179Tfs*10 | Frame Shift Del (DEL) | VAF 306/327 reads (94%) | called by pindel, varscan2
- PTPRQ | c.2881T>C p.Y961H (on ENST00000616559; = p.Y919H on NM_001145026.2) | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- RIMS1 | c.1301C>A p.A434E | Missense Mutation (SNP) | VAF 180/870 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, varscan2
- SELPLG | c.1239G>C p.*413Yext*73 | Nonstop Mutation (SNP) | VAF 16/316 reads (5%) | called by muse, mutect2
- SEPTIN9 | c.664A>T p.R222W (on ENST00000427177 / NM_001113491.2; = p.R204W on NM_006640.4) | Missense Mutation (SNP) | VAF 182/770 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SUGCT | c.1118T>A p.M373K (on ENST00000335693 / NM_001193313.2; = p.M399K on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- TFAP2A | c.1037T>C p.I346T (on ENST00000482890; = p.I338T on NM_001032280.3) | Missense Mutation (SNP) | VAF 404/404 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TTC7B | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VSIG10L2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 301/789 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- AIFM1 | c.1584C>T p.I528= | Silent (SNP) | VAF 195/321 reads (61%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.2697T>C p.I899= | Silent (SNP) | VAF 125/432 reads (29%) | called by muse, mutect2, varscan2
- BMP2K | c.2910C>T p.V970= | Silent (SNP) | VAF 110/300 reads (37%) | called by muse, mutect2, varscan2
- BTBD11 | c.1341C>T p.H447= | Silent (SNP) | VAF 196/424 reads (46%) | catalogued as rs377331056, COSV99775302; called by muse, varscan2
- CAMK1D | c.882C>T p.S294= | Silent (SNP) | VAF 264/553 reads (48%) | catalogued as rs200929443, COSV66612076; called by muse, varscan2
- CAMK2N1 | c.234C>T p.V78= | Silent (SNP) | VAF 90/272 reads (33%) | called by muse, mutect2, varscan2
- CDH7 | c.135C>A p.T45= | Silent (SNP) | VAF 150/150 reads (100%) | called by muse, mutect2, varscan2
- CEP295NL | c.1698A>T p.G566= | Silent (SNP) | VAF 257/659 reads (39%) | called by muse, mutect2, varscan2
- CHST2 | c.399C>T p.V133= | Silent (SNP) | VAF 269/1191 reads (23%) | catalogued as rs768853251, COSV58885490; called by muse, mutect2, varscan2
- EFCAB8 | c.3795C>T p.F1265= | Silent (SNP) | VAF 650/867 reads (75%) | catalogued as rs1486624705; called by muse, mutect2, varscan2
- FNDC1 | c.2682G>C p.V894= | Silent (SNP) | VAF 781/781 reads (100%) | called by muse, mutect2, varscan2
- GALNT17 | c.85C>A p.R29= | Silent (SNP) | VAF 254/568 reads (45%) | called by muse, mutect2, varscan2
- HSD11B1 | c.528T>G p.A176= | Silent (SNP) | VAF 56/113 reads (50%) | called by muse, mutect2, varscan2
- HSDL1 | c.798G>A p.S266= | Silent (SNP) | VAF 164/476 reads (34%) | catalogued as rs567519432; called by muse, mutect2, varscan2
- KCNV1 | c.84C>T p.S28= | Silent (SNP) | VAF 476/719 reads (66%) | catalogued as COSV52084658; called by muse, mutect2, varscan2
- LRFN5 | c.1557C>T p.F519= | Silent (SNP) | VAF 117/247 reads (47%) | catalogued as COSV53258158; called by muse, mutect2, varscan2
- MICAL2 | c.1737C>T p.L579= | Silent (SNP) | VAF 319/560 reads (57%) | catalogued as rs754326645; called by muse, mutect2, varscan2
- NEB | c.5814C>T p.L1938= | Silent (SNP) | VAF 132/270 reads (49%) | called by muse, mutect2, varscan2
- PCDH15 | c.4564T>C p.L1522= | Silent (SNP) | VAF 55/174 reads (32%) | catalogued as rs772345833; called by muse, mutect2, varscan2
- PCDHA9 | c.1815G>C p.A605= | Silent (SNP) | VAF 22/766 reads (3%) | catalogued as COSV65326327; called by muse, mutect2
- PCDHB2 | c.2094G>A p.S698= | Silent (SNP) | VAF 335/1161 reads (29%) | catalogued as COSV50626856; called by muse, mutect2, varscan2
- PHLDB2 | c.876T>G p.P292= | Silent (SNP) | VAF 56/199 reads (28%) | called by muse, mutect2, varscan2
- PRKAA1 | c.957C>T p.L319= | Silent (SNP) | VAF 109/109 reads (100%) | called by muse, mutect2, varscan2
- PRLHR | c.1077C>T p.P359= | Silent (SNP) | VAF 264/382 reads (69%) | called by muse, mutect2, varscan2
- RBMXL2 | c.534C>T p.R178= | Silent (SNP) | VAF 333/784 reads (42%) | called by muse, mutect2, varscan2
- RYR1 | c.10263G>A p.A3421= | Silent (SNP) | VAF 119/360 reads (33%) | catalogued as rs778171066, COSV62087945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPC4 | c.1458C>A p.I486= | Silent (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- URB2 | c.915C>G p.A305= | Silent (SNP) | VAF 181/561 reads (32%) | called by muse, mutect2, varscan2
- HBS1L | c.430+1891G>C | Intron (SNP) | VAF 105/211 reads (50%) | called by muse, mutect2, varscan2
- LEKR1 | c.*976C>G | 3'UTR (SNP) | VAF 43/174 reads (25%) | catalogued as rs769277375, COSV104414655; called by muse, mutect2, varscan2
- MYCBP2 | c.*462T>A | 3'UTR (SNP) | VAF 10/105 reads (10%) | catalogued as rs1392056188; called by muse, mutect2
